Gene-level copy-number profile of tumor specimen TCGA-J2-8192-01A from TCGA case TCGA-J2-8192, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 65.4 years (23,892 days).
Specimen TCGA-J2-8192-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.b75da915-f48d-411b-b11f-41c086c46347.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-J2-8192-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1024a4e1-340e-4916-89b3-384e30bcf902

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 1: 492; copy number 2: 18,758; copy number 3: 27,453; copy number 4: 9,127; copy number 5: 2,095; copy number 6: 687; copy number 7: 1,183.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-J2-8192-01A-11D-2237-01): tumor purity 0.41, ploidy 2.76, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,638,285–23,438,700, 24 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,183 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–57,773,199, 1,068 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr14:67,386,984–71,928,596, 114 genes, copy number 7 (broad region; genes not listed).
- chr14:72,022,407–72,022,516, 1 gene, copy number 7: Y_RNA.

Autosomal genes at a single copy (total copy number 1): 492. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
